Surgical pathology report (de-identified scan), TCGA case TCGA-09-1664, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1664-01A (Primary Tumor).

[page 1 of 6]
A: R adenexa (FS)

H&E, First x 1

C: Uterus +/- tubes/ovaries, neoplastic

H&E, First x 1

E: Bladder implant

H&E, First x 1

F: R common iliac lymph node

H&E, FIRST X 1

G: R paraaortic lymph node

H&E, First x 1

H: L pelvic lymph node

H&E, First x 1

I: L common iliac

H&E, First x 1

1: 1 periaortic

FILE, FIRST X 1

K: Diaphragm tumor

H&E, First x 1

L: Appendix, incidental

H&E, First X 1

M: Sigmoid implant

H&E, First x 1

N: Omentum

H&E, First x 1

Page 1 of 6

A. Right adnexa, salpingo-oophorectomy: Papillary serous cystadenocarcinoma extensively involving ovary with serosal metastasis to fallopian tube.
B. Soft tissue, "sigmoid implant," biopsy: Metastatic papillary serous cystadenocarcinoma.

[page 2 of 6]
C. Uterus and left adnexa, total abdominal hysterectomy and left salpingo-oophorectomy:

- Cervix: Endocervical and squamous mucosa with no significant pathologic abnormality; no dysplasia or carcinoma identified.
- Endometrium: Proliferative pattern, no hyperplasia or carcinoma identified.
- Myometrium: No significant pathologic abnormality.
- Serosa: Metastatic papillary serous cystadenocarcinoma.
- Bilateral parametrial soft tissue: Metastatic papillary serous cystadenocarcinoma.
- Left ovary: Extensively involved by papillary serous cystadenocarcinoma.
- Left fallopian tube: Metastatic papillary serous cystadenocarcinoma.

D. Lymph node, pelvic, biopsy: Three lymph nodes with no tumor identified (0/3).

E. Soft tissue, "bladder implant," biopsy: Metastatic papillary cystadenocarcinoma.

F. Lymph node, right common iliac, dissection: Four lymph nodes with no tumor identified (0/4).

G. Lymph node, right para-aortic, dissection: Five lymph nodes with no tumor identified (0/5).

H. Lymph node, left pelvic, dissection: Papillary serous cystadenocarcinoma metastatic to one of eleven lymph nodes (1/11).

I. Lymph node, left common iliac, dissection: Three lymph nodes with no tumor identified (0/3).

J. Lymph node, left para-aortic, dissection: Five lymph nodes with no tumor identified (0/5).

K. Soft tissue, "diaphragm tumor," biopsy: Metastatic papillary serous cystadenocarcinoma.

L. Appendix, appendectomy: Serosal fibrosis and chronic inflammation, no tumor identified.

M. Soft tissue, "sigmoid implant," biopsy: Metastatic papillary serous cystadenocarcinoma.

Page 2 of 6

N. Soft tissue, omentum, biopsy: Metastatic papillary serous cystadenocarcinoma.

Note: Ovarian Tumor Synoptic Comment

1. Type of tumor: Papillary serous cystadenocarcinoma.
2. Grade of tumor: Grade 1.
3. Location of tumor: Bilateral.
4. Diameter of tumor: 15.0 cm right, 10.5 cm left.
5. Appearance of surface of ovary: Tumor on surface bilaterally.
6. Condition of capsule: Intact bilaterally.
7. Appearance of cut surface: Multilocular cysts bilaterally.
8. Color of solid areas: Tan.
9. Necrosis: None present.
10. Lymphatic/vascular invasion: Not present.
11. Sites of metastases in pelvis: Bilateral parametria, bladder serosa, one left pelvic lymph node, bilateral fallopian tubes.
12. Sites of metastases in abdomen: Omentum, sigmoid colon serosa, diaphragm.

[page 3 of 6]
[REDACTED]

13. Para-aortic lymph nodes: Ten lymph nodes with no tumor identified (0/10).

14. Peritoneal cytology: Pending processing.

Cytology accession number: [REDACTED]

15. Other significant findings: A total of thirty one lymph nodes are identified, including metastasis to one

left pelvic lymph node (1/31).

16. FIGO stage: IIIC.

17. TNM stage: pT3cN1M0.

Intraoperative Consult Diagnosis

FS1 (A) Right adnexal mass, excision: Micropapillary borderline tumor versus low-grade serous carcinoma. [REDACTED]

FS2 (A) Right adnexal mass, excision: Micropapillary borderline tumor versus low-grade serous carcinoma. [REDACTED]

FS3 (B) "Sigmoid implant #3," biopsy: Tumor implant, invasiveness not determined. [REDACTED]

Clinical History

The patient is a [REDACTED] G2 P1, with an 18.0-cm complex pelvic mass and omental cake with a CA125 of

1,746. She undergoes exploratory laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, PLND, PALND, radical pelvic dissection, omentectomy, appendectomy, peritoneal stripping, and tumor debulking.

Gross Description

The specimen is received fresh in fourteen parts, each labeled with the patient's name and medical record number.

Part A is additionally labeled [REDACTED] and consists of a right ovary and fallopian tube, weighing

570 gm and measuring 15.0 x 14.0 x 6.0 cm. The tube portion of the specimen measures 6.7 cm in length

x 1.0 cm in average diameter. the ovary is massively enlarged and multicystic with diffuse tan to dark red,

friable, sessile lesions studding the outside of the mass. The specimen is opened to reveal roughly 300 cc of

viscous, cloudy, yellow fluid. The cut surface of the specimen is multicystic with some areas being relatively smooth-walled and others being apparently filled with tan, somewhat friable tumor. Two areas of

the tumor are inked overlying the shaggy, hemorrhagic-appearing external portion, and sections through

these are taken and submitted for frozen sections 1 and 2. The frozen section remnants are submitted in

cassettes [REDACTED] respectively. Fourteen representative sections of solid, cystic, and papillary areas of

tumor are submitted in cassettes [REDACTED]. Multiple representative sections of tube are submitted in cassette [REDACTED]

Part B is additionally labeled "3 - sigmoid implant #3 (FS)," and consists of a single irregular, unoriented

piece of pink-red, soft tissue measuring 1.0 x 0.8 x 0.5 cm. The specimen is entirely frozen to perform

frozen section diagnosis 3, and the remnant is submitted in cassette [REDACTED]

[page 4 of 6]
[REDACTED]

Part C is received fresh, not additionally labeled, and consists of a uterus and left ovary and fallopian tube, weighing 435 gm. The uterine portion of the specimen measures 7.5 x 7.2 x 5.2 cm. The left ovary measures 10.5 x 7.0 x 5.8 cm. The left tube measures 9.2 cm in length x 1.2-2.2 cm in diameter. The left ovary is covered almost entirely by large, tan-pink to red, papillary, frond-like excrescences. The underlying ovary is soft and multicystic. There is a large paratubal cyst measuring 3.0 x 2.7 x 2.1 cm. The serosal surface of the uterus is studded with similar papillary excrescences as the ovary, although they are much smaller and more sessile. The cervix is slightly rough, but tan and otherwise unremarkable. The uterus is opened to reveal the endometrial cavity to be 3.2 cm in length x 1.2 cm in width, and grossly unremarkable.

Likewise, the myometrium appears unremarkable. Tissue is submitted in cassettes as follows:

[REDACTED] Representative section of anterior cervix.

[REDACTED] Representative section of posterior cervix.

[REDACTED] Representative section through the posterior lower uterine segment.

[REDACTED] Two representative sections through anterior endometrium.

[REDACTED] Two representative sections through posterior myometrium.

[REDACTED] Two representative sections of serosa through areas of apparent involvement with tumor.

[REDACTED] Multiple representative sections of right parametrium.

[REDACTED] Multiple representative sections of left parametrium.

[REDACTED] Multiple representative sections of left fallopian tube.

[REDACTED] Cassettes of [REDACTED] Multiple representative sections of left ovary tumor (including papillary excrescences and necrotic-appearing areas).

Part D is received fresh, additionally labeled "4 - R pelvic lymph node perm [REDACTED] OR 12," and consists

of multiple irregular fragments of yellow, fibrofatty-appearing tissue measuring 4.4 x 3.0 x 1.2 cm in

aggregate. Three candidate lymph nodes are identified, and the fatty remnants are removed and returned

to the container. The candidate lymph nodes are submitted in cassette [REDACTED] 1.

Part E is received fresh, additionally labeled "13 - bladder implant," and consists of a single unoriented,

irregular fragment of tan-pink to yellow, soft and friable-appearing tissue measuring 2.3 x 0.5 x 0.3 cm in

aggregate. The specimen is entirely submitted in cassette [REDACTED]

Part F is additionally labeled "5 - R common iliac lymph node (perm)," and consists of multiple irregular,

unoriented, soft pieces of yellow and fibrofatty-appearing tissue measuring 3.2 x 2.3 x 0.5 cm in aggregate.

Multiple candidate lymph nodes are identified, and the fatty remnants are trimmed and returned to the

container. The candidate lymph nodes are wrapped in tissue paper and submitted in cassette [REDACTED]

Part G is received fresh, additionally labeled "6 - right peri-aortic lymph node (perm)," and consists of

multiple irregular, unoriented fragments of tan-pink, soft to rubbery tissue measuring 2.3 x 1.7 x

[page 5 of 6]
length x 7.0 cm in width x 1.2 cm in depth. There are multiple firm to hard nodules studding the cementum. Representative sections of four discrete nodules are submitted in cassette.

[page 6 of 6]
[REDACTED]

LABORATORY CONFIDENTIALITY REPORT

[REDACTED]

[REDACTED]

Other Specimens

[REDACTED]

Specimen(s) Received: Vaginal, Thin Prep

Final Diagnosis

Vaginal, Thin Prep

NEGATIVE FOR INTRAEPITHELIAL LESION OR MALIGNANCY.

Hyperkeratosis.

SPECIMEN ADEQUACY:

Satisfactory for evaluation.

[REDACTED]

[REDACTED]

Specimen(s) Received: Peritoneal Washing

Final Diagnosis

Peritoneal Washing

ADENOCARCINOMA, METASTATIC.

Acute inflammation.

[REDACTED]

Source: NCI Genomic Data Commons file c0011f74-222b-47a6-9812-bf99b3a84fe3 (TCGA-09-1664.1E80516C-0CC5-4A3B-ABAE-054C57CA7B3C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).